Somatic mutation profile of tumor specimen ALCH-B0ED-TTP1-A (aliquot ALCH-B0ED-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0ED, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.1 years (21,203 days).
Specimen ALCH-B0ED-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cfcca0f-a87e-47a6-b808-49ceccfacf2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0ED-NB1-A (Blood Derived Normal), aliquot ALCH-B0ED-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b24af48-dfcb-4b74-ada9-5cd8f89009ac

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, Intron 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1F | c.3504G>T p.Q1168H | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs782392576; called by muse, mutect2
- COL7A1 | c.4777G>C p.D1593H | Missense Mutation (SNP) | VAF 15/566 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60394466; called by muse, mutect2
- COX15 | c.586C>G p.L196V | Missense Mutation (SNP) | VAF 78/848 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV50012164; called by muse, mutect2
- PIGC | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 9/250 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV51131178; called by muse, mutect2
- SELENOW | c.30-8C>T | Splice Region (SNP) | VAF 13/188 reads (7%) | catalogued as rs1472495307; called by muse, mutect2
- AC104452.1 | c.1316T>A p.V439E | Missense Mutation (SNP) | VAF 46/646 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADCY9 | c.2549C>T p.A850V | Missense Mutation (SNP) | VAF 21/290 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- CCDC141 | c.653T>C p.L218P | Missense Mutation (SNP) | VAF 16/540 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GCNT2 | c.14G>C p.W5S | Missense Mutation (SNP) | VAF 42/420 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); called by muse, mutect2
- GTF2A1 | c.13G>C p.A5P | Missense Mutation (SNP) | VAF 42/633 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.166); called by muse, mutect2
- KLHL33 | c.1273_1274insA p.G425Efs*4 | Frame Shift Ins (INS) | VAF 64/418 reads (15%) | called by mutect2, pindel, varscan2
- PAPPA2 | c.5021G>T p.G1674V | Missense Mutation (SNP) | VAF 16/546 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- RGSL1 | c.166A>G p.N56D | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ROBO1 | c.4079G>A p.G1360E | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, mutect2
- THBS2 | c.1825C>T p.R609C | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZNF729 | c.3450T>A p.H1150Q | Missense Mutation (SNP) | VAF 12/361 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ATRNL1 | c.1782T>C p.Y594= | Silent (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- MEFV | c.780C>A p.L260= | Silent (SNP) | VAF 35/870 reads (4%) | catalogued as COSV54826807; called by muse, mutect2
- RFTN1 | c.360A>G p.E120= | Silent (SNP) | VAF 46/496 reads (9%) | catalogued as rs1425025151; called by muse, mutect2
- HBE1 | c.-267+102896T>A | Intron (SNP) | VAF 22/362 reads (6%) | called by muse, mutect2
